Somatic mutation profile of tumor specimen TCGA-55-7914-01A (aliquot TCGA-55-7914-01A-11D-2167-08) from TCGA case TCGA-55-7914, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.5 years (26,105 days).
Specimen TCGA-55-7914-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c5b5776-e87b-4a6d-881b-e0c4ecd38af6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7914-10A (Blood Derived Normal), aliquot TCGA-55-7914-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cc6c97b-1e0d-497e-9d18-fce6c24fb7dd

The open-access MAF lists 189 somatic variants for this specimen: 146 protein-altering or splice-affecting, 41 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 41, Nonsense Mutation 7, Frame Shift Del 6, Splice Site 2, Frame Shift Ins 1, Translation Start Site 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6259G>A p.G2087R | Missense Mutation (SNP) | VAF 33/71 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553153748, COSV61371196, COSV61381160; ClinVar: other; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC2 | c.1462C>G p.Q488E | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); catalogued as COSV64984663; called by muse, mutect2, varscan2
- ADD3 | c.729G>T p.M243I | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV53320254, COSV53321231; called by muse, mutect2, varscan2
- ADGRD1 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs755377639, COSV55439450, COSV55451837; called by muse, mutect2, varscan2
- ADGRG4 | c.6533T>C p.L2178P | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV54950125; called by muse, mutect2, varscan2
- AMER2 | c.1914A>T p.K638N | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63436308; called by muse, mutect2, varscan2
- APAF1 | c.149A>T p.Q50L | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV54488550; called by muse, mutect2, varscan2
- APOB | c.1970G>T p.G657V | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51924281; called by muse, mutect2
- ASB2 | c.695A>G p.Q232R | Missense Mutation (SNP) | VAF 86/291 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.422); catalogued as COSV60110608; called by muse, mutect2, varscan2
- ASXL3 | c.1101G>T p.E367D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as COSV52458037, COSV52458842; called by muse, varscan2
- ATP8A2 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV54938074, COSV54939738; called by muse, mutect2, varscan2
- ATP8B4 | c.158A>G p.Q53R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV99464113; called by mutect2, varscan2
- AURKC | c.257A>G p.H86R (on ENST00000302804 / NM_001015878.2; = p.H52R on NM_003160.3) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV57137054; called by muse, mutect2, varscan2
- BAG3 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1047671466, COSV64841654; called by muse, mutect2, varscan2
- BAZ2B | c.5813G>A p.R1938Q | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.398); catalogued as rs764943316, COSV58596141; called by muse, mutect2, varscan2
- BTBD3 | c.433G>T p.G145W | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54777963; called by muse, mutect2, varscan2
- CAMKV | c.1154G>A p.S385N | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as COSV56554106; called by muse, mutect2, varscan2
- CBX3 | c.24+1G>A p.X8_splice | Splice Site (SNP) | VAF 7/87 reads (8%) | catalogued as COSV61158100; called by muse, mutect2
- CCDC148 | c.821A>G p.Y274C | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51754785; called by muse, mutect2, varscan2
- CD200R1 | c.748C>A p.L250I (on ENST00000471858 / NM_170780.3; = p.L273I on NM_138806.4) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.558); catalogued as COSV99866813; called by muse, mutect2, varscan2
- CHRFAM7A | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55396934; called by mutect2, varscan2
- CHSY3 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV59271765, COSV59277861; called by muse, mutect2, varscan2
- CLDND1 | c.598C>G p.Q200E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV57858212; called by muse, mutect2, varscan2
- CLIP1 | c.1727A>G p.H576R (on ENST00000620786 / NM_001247997.1; = p.H565R on NM_002956.2) | Missense Mutation (SNP) | VAF 57/362 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs780646864, COSV56797699; called by muse, mutect2, varscan2
- COL6A2 | c.2449C>T p.P817S | Missense Mutation (SNP) | VAF 100/181 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs764353086, COSV55999453, COSV56003969; called by muse, mutect2, varscan2
- CROT | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58972905; called by muse, mutect2, varscan2
- CTTNBP2 | c.2720A>T p.N907I | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50390035; called by muse, mutect2, varscan2
- DCAF10 | c.1105T>A p.C369S | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV54287080; called by muse, mutect2, varscan2
- DDHD1 | c.1097A>C p.E366A (on ENST00000323669; = p.E563A on NM_030637.3) | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV60357432; called by muse, mutect2, varscan2
- DPY19L3 | c.270G>C p.E90D | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.956); catalogued as COSV60474753; called by muse, mutect2, varscan2
- DSTN | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV55712269; called by muse, mutect2, varscan2
- EXOC1 | c.2676G>T p.Q892H | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV62119204; called by muse, mutect2, varscan2
- EYA1 | c.1417G>T p.A473S | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV58157427; called by muse, mutect2, varscan2
- F5 | c.3088C>T p.R1030* | Nonsense Mutation (SNP) | VAF 110/327 reads (34%) | catalogued as rs780253174, CM032892, COSV63120947; called by muse, mutect2, varscan2
- FAM111A | c.1354G>T p.V452L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as COSV64655056; called by muse, mutect2, varscan2
- FBXW7 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as COSV55895350, COSV55921956; called by muse, mutect2, varscan2
- FMO1 | c.911A>G p.K304R | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.859); catalogued as COSV61444689; called by muse, mutect2, varscan2
- FN3KRP | c.168G>T p.M56I | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV53928937; called by muse, mutect2, varscan2
- FREM1 | c.4568G>T p.G1523V | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV66518195; called by muse, mutect2, varscan2
- FRMPD2 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs1298449929, COSV100563572; called by muse, mutect2
- FRMPD2 | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.243); catalogued as COSV100563573; called by muse, mutect2, varscan2
- GLRA1 | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.084); catalogued as COSV51007694; called by muse, mutect2, varscan2
- GPR83 | c.513G>T p.Q171H | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV54717591; called by muse, mutect2, varscan2
- GPRIN3 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV60884143; called by muse, mutect2, varscan2
- H3C8 | c.397G>T p.G133W | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV59952617; called by muse, mutect2, varscan2
- HJURP | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.22); catalogued as COSV64978510; called by muse, mutect2, varscan2
- HS6ST3 | c.1132C>G p.Q378E | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100940321, COSV65002569; called by muse, mutect2, varscan2
- IL16 | c.1184T>A p.L395Q | Missense Mutation (SNP) | VAF 53/291 reads (18%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.946); catalogued as COSV57260553; called by muse, mutect2, varscan2
- IMPDH1 | c.569G>T p.G190V (on ENST00000470772 / NM_001142573.2; = p.G276V on NM_000883.4) | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV58315040; called by muse, mutect2, varscan2
- JAKMIP1 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); catalogued as rs749938147, COSV51522733; called by muse, mutect2, varscan2
- KCNS2 | c.1144C>A p.P382T | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54637369, COSV54638642; called by muse, mutect2, varscan2
- KIF4B | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV70527972; called by muse, mutect2, varscan2
- KLHL9 | c.850C>G p.P284A | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV62921195; called by muse, mutect2, varscan2
- LGR5 | c.516T>G p.N172K | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57002483; called by muse, mutect2, varscan2
- LHCGR | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV54292957; called by muse, mutect2, varscan2
- LIMCH1 | c.3182G>A p.R1061Q | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754710831, COSV58274118; called by muse, mutect2, varscan2
- LRP1 | c.5210T>G p.L1737R | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54502650; called by muse, mutect2, varscan2
- LRPPRC | c.1106del p.P369Qfs*13 | Frame Shift Del (DEL) | VAF 18/96 reads (19%) | catalogued as COSV99580547; called by mutect2, pindel, varscan2
- LRRC49 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); catalogued as COSV51436220; called by muse, mutect2, varscan2
- MPPED1 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV68837436; called by muse, mutect2, varscan2
- MTIF2 | c.1974dup p.F659Ifs*2 | Frame Shift Ins (INS) | VAF 21/83 reads (25%) | catalogued as rs770359991; called by mutect2, varscan2
- MTRF1 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53480776; called by muse, mutect2, varscan2
- MUC16 | c.38769G>A p.M12923I | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV67446785; called by muse, mutect2, varscan2
- MYCBP2 | c.9781G>T p.V3261L (on ENST00000357337; = p.V3299L on NM_015057.5) | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.177); catalogued as COSV62010924; called by muse, mutect2, varscan2
- NAV2 | c.5840A>G p.E1947G (on ENST00000396087 / NM_001244963.2; = p.E1888G on NM_145117.5) | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV60656696; called by muse, mutect2, varscan2
- NOS2 | c.3181C>T p.R1061W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs200470759, COSV58221934, COSV58222238; called by muse, mutect2, varscan2
- NSUN5 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV53090392; called by muse, mutect2, varscan2
- OCA2 | c.774C>A p.D258E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100667034; called by muse, varscan2
- OR1C1 | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.773); catalogued as COSV68715396; called by muse, mutect2, varscan2
- OR1D2 | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV58921059; called by muse, mutect2, varscan2
- OR2A25 | c.109A>C p.I37L | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV68716880; called by muse, mutect2, varscan2
- OR2F2 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV68832559, COSV68832730; called by muse, mutect2, varscan2
- OR2G2 | c.766G>T p.G256* | Nonsense Mutation (SNP) | VAF 60/144 reads (42%) | catalogued as COSV60739414, COSV60739495; called by muse, mutect2, varscan2
- OR2M4 | c.877C>G p.R293G | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV60708785, COSV60708977; called by muse, mutect2, varscan2
- OR2W3 | c.341T>A p.L114H | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64456073; called by muse, mutect2, varscan2
- OR5D13 | c.763G>C p.G255R | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100686900, COSV62332778, COSV62332962; called by muse, mutect2, varscan2
- OR6F1 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 61/159 reads (38%) | catalogued as COSV57466901; called by muse, mutect2, varscan2
- OR8J3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1217984741, COSV56879508; called by mutect2, varscan2
- OR8K5 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV57887892, COSV57887935; called by muse, mutect2, varscan2
- PARP10 | c.2306C>T p.T769I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1310618456, COSV57296812; called by muse, mutect2, varscan2
- PCDHA4 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.082); catalogued as COSV63539102; called by muse, mutect2, varscan2
- PCDHB13 | c.628A>T p.R210W | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV53393397; called by muse, mutect2, varscan2
- PCDHGB6 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV53903543; called by muse, mutect2, varscan2
- PCDHGC4 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs534793835, COSV52744385; called by muse, mutect2, varscan2
- PCNT | c.1320G>C p.E440D | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV64025316; called by muse, mutect2, varscan2
- PCNX1 | c.3067C>G p.L1023V | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV53089691, COSV53093514, COSV53101840; called by muse, mutect2, varscan2
- PDE10A | c.1438G>T p.G480C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.304); catalogued as COSV63091518; called by muse, mutect2, varscan2
- PDE9A | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs201884723; called by muse, mutect2, varscan2
- PEPD | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV54887282, COSV99729049; called by muse, mutect2
- PIGS | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs138187632; called by muse, mutect2, varscan2
- PLEKHF1 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1460524571, COSV71409942; called by muse, mutect2
- POLR3G | c.192G>C p.L64F | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.069); catalogued as COSV67624843; called by muse, mutect2, varscan2
- PPIAL4A | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as rs1473806168; called by muse, mutect2, varscan2
- PPP1R17 | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.677); catalogued as rs1482894095, COSV59610632; called by muse, mutect2, varscan2
- PPP2R5B | c.311G>C p.R104P | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51209735; called by muse, mutect2, varscan2
- PRDM10 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1282877066, COSV58799467; called by muse, mutect2, varscan2
- PRPSAP1 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 23/107 reads (21%) | catalogued as COSV61210467; called by muse, mutect2, varscan2
- PUM2 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57578062; called by muse, mutect2, varscan2
- PYHIN1 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as COSV100932350, COSV100932403, COSV63721376; called by muse, mutect2, varscan2
- RAD51AP2 | c.2788C>G p.Q930E | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV67587357; called by muse, mutect2, varscan2
- RNF139 | c.105C>A p.D35E | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57834130; called by muse, mutect2
- ROCK2 | c.1462-2A>C p.X488_splice | Splice Site (SNP) | VAF 11/43 reads (26%) | catalogued as COSV55076054; called by muse, mutect2
- RPS6KB1 | c.1165C>G p.Q389E | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV56675397; called by muse, mutect2, varscan2
- RXRG | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63231499; called by muse, mutect2, varscan2
- SAG | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV68590352; called by muse, mutect2, varscan2
- SEC24D | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54877095; called by muse, mutect2, varscan2
- SERPINB11 | c.62G>T p.S21I | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV66956451; called by muse, mutect2, varscan2
- SGSM2 | c.1324C>T p.P442S (on ENST00000426855 / NM_001098509.2; = p.P487S on NM_014853.3) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV52155925; called by muse, mutect2, varscan2
- SHANK1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV99520407; called by muse, mutect2
- SHC4 | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60109559; called by muse, mutect2, varscan2
- SI | c.1656G>T p.W552C | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV52278400, COSV52295798; called by muse, mutect2, varscan2
- SI | c.1655G>C p.W552S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV100014346; called by muse, mutect2, varscan2
- SLC12A7 | c.2383T>A p.W795R | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53754699; called by muse, mutect2, varscan2
- SLC41A2 | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 27/358 reads (8%) | catalogued as rs540046926, COSV51602220; called by muse, mutect2
- SLC9A2 | c.1597T>C p.F533L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV52128916; called by muse, mutect2, varscan2
- SULT1C3 | c.94T>C p.S32P | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs1316232273, COSV61252431; called by muse, mutect2, varscan2
- TAS2R41 | c.469C>G p.Q157E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as rs377524079, COSV68765154; called by muse, mutect2, varscan2
- TBX3 | c.1010A>G p.D337G (on ENST00000257566 / NM_016569.4; = p.D317G on NM_005996.4) | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57469422; called by muse, mutect2, varscan2
- TEX26 | c.77G>T p.W26L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66839380; called by muse, mutect2, varscan2
- TEX26 | c.78G>T p.W26C | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100994029; called by muse, mutect2, varscan2
- TNFSF11 | c.346T>A p.C116S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53476520; called by muse, mutect2, varscan2
- TP53 | c.880del p.E294Sfs*51 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | catalogued as CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; called by mutect2, pindel, varscan2
- TRIM27 | c.1302G>T p.Q434H | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.958); catalogued as COSV101019334, COSV65873304; called by muse, mutect2, varscan2
- TRPM5 | c.2725G>A p.V909M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50144926; called by muse, mutect2, varscan2
- TSR1 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52155918; called by muse, mutect2, varscan2
- TTN | c.59176C>A p.P19726T (on ENST00000591111; = p.P12302T on NM_003319.4) | Missense Mutation (SNP) | VAF 25/120 reads (21%) | PolyPhen probably damaging (0.999); catalogued as COSV59900806; called by muse, mutect2, varscan2
- TWNK | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV61325709; called by muse, mutect2, varscan2
- UGT1A9 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs570830637, COSV60832299, COSV60840417; called by muse, mutect2, varscan2
- VCX | c.174G>T p.K58N | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100406219; called by muse, varscan2
- VGLL4 | c.691G>C p.V231L | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.919); catalogued as rs147755206, COSV56079850; called by muse, mutect2, varscan2
- VPS13B | c.10883C>T p.A3628V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as rs762394387, COSV62133778; called by muse, mutect2, varscan2
- YEATS2 | c.3591A>T p.R1197S | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59361754; called by muse, mutect2, varscan2
- ZBTB26 | c.910G>T p.G304C | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65402791; called by muse, mutect2, varscan2
- ZNF217 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV56594190; called by muse, mutect2, varscan2
- ZNF251 | c.505A>T p.T169S | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV52956319; called by muse, mutect2, varscan2
- ZNF382 | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53086282, COSV53086899; called by muse, mutect2, varscan2
- ZNF532 | c.3673G>A p.V1225I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs142104041; called by muse, mutect2, varscan2
- ZNF536 | c.1048T>G p.C350G | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62819020; called by muse, mutect2, varscan2
- ABCC11 | c.1463_1465delinsAT p.P488Hfs*20 | Frame Shift Del (DEL) | VAF 39/155 reads (25%) | called by pindel, varscan2*
- ELL3 | c.594_606del p.E199Hfs*19 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel
- OR10A2 | c.681_683delinsTT p.C228Ffs*15 | Frame Shift Del (DEL) | VAF 36/233 reads (15%) | called by pindel, varscan2*
- OR5T1 | c.943del p.R315Dfs*4 | Frame Shift Del (DEL) | VAF 29/115 reads (25%) | called by mutect2, pindel, varscan2
- SSU72P8 | c.571G>T p.V191F | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- TRAV26-2 | c.228G>T p.M76I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV27 | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACAN | c.2970G>A p.E990= | Silent (SNP) | VAF 34/252 reads (13%) | catalogued as COSV100717263; called by muse, varscan2
- AK9 | c.2865C>T p.A955= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as rs138836954; called by muse, mutect2, varscan2
- APOH | c.1011T>G p.T337= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV52771492; called by muse, mutect2, varscan2
- ASGR2 | c.165C>T p.S55= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV54689319; called by muse, mutect2
- ATP8B4 | c.2967T>A p.A989= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV52709721; called by muse, mutect2, varscan2
- CD200R1 | c.747C>A p.I249= (on ENST00000471858 / NM_170780.3; = p.I272= on NM_138806.4) | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99866820; called by muse, mutect2, varscan2
- CDH22 | c.1143G>C p.V381= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100952965, COSV64836533; called by muse, mutect2
- CLDN25 | c.475C>A p.R159= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV71620410, COSV71620477, COSV71620502; called by muse, mutect2
- CYB5R4 | c.612T>C p.F204= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV63750166; called by muse, mutect2, varscan2
- DNAH5 | c.13389A>G p.E4463= | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as COSV54205263; called by muse, mutect2, varscan2
- DTNA | c.1017C>G p.P339= | Silent (SNP) | VAF 25/141 reads (18%) | catalogued as COSV51991708; called by muse, mutect2, varscan2
- EDAR | c.24G>C p.T8= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as COSV51500015, COSV51500127, COSV99304016; called by muse, mutect2, varscan2
- ELP5 | c.45G>A p.L15= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV59708306; called by muse, mutect2, varscan2
- FAM227B | c.915G>C p.L305= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV54805950; called by muse, mutect2, varscan2
- GON4L | c.3786C>T p.F1262= | Silent (SNP) | VAF 9/121 reads (7%) | catalogued as rs200394500, COSV55187491; called by muse, mutect2
- HERC2 | c.6129C>T p.L2043= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs1160723712, COSV55308786; called by muse, mutect2, varscan2
- KDM5C | c.2289G>T p.L763= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV64762917; called by muse, mutect2, varscan2
- KLHL12 | c.1281G>A p.V427= | Silent (SNP) | VAF 55/227 reads (24%) | catalogued as COSV66126993; called by muse, mutect2, varscan2
- KRT32 | c.1074C>A p.I358= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as COSV56785540; called by muse, mutect2, varscan2
- KRT74 | c.1164C>T p.D388= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs185121430; called by mutect2, varscan2
- LYNX1-SLURP2 | c.243T>C p.C81= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100235453; called by mutect2, varscan2
- MAP1B | c.4098T>C p.S1366= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as rs760180077, COSV57094144; called by muse, mutect2, varscan2
- MROH9 | c.207C>A p.S69= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV63010093; called by muse, mutect2, varscan2
- MTUS2 | c.48G>T p.R16= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV70913877; called by muse, mutect2, varscan2
- MYLK | c.1041G>A p.L347= | Silent (SNP) | VAF 45/169 reads (27%) | catalogued as COSV60605192; called by muse, mutect2, varscan2
- NLRP11 | c.2307C>A p.A769= | Silent (SNP) | VAF 78/357 reads (22%) | catalogued as COSV64085774; called by muse, mutect2, varscan2
- NRG2 | c.969G>T p.R323= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV56829661; called by muse, mutect2, varscan2
- OGFR | c.1227G>A p.K409= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV51696812; called by muse, mutect2, varscan2
- OR10G7 | c.348C>T p.V116= | Silent (SNP) | VAF 50/165 reads (30%) | catalogued as COSV57865710, COSV57866709; called by muse, mutect2, varscan2
- OR2L2 | c.333G>T p.G111= | Silent (SNP) | VAF 52/237 reads (22%) | catalogued as COSV63548499; called by muse, mutect2, varscan2
- OR5I1 | c.294G>T p.G98= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV56885597; called by muse, mutect2
- PCDHGA11 | c.1218A>T p.I406= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV53903549; called by muse, mutect2, varscan2
- PITPNM1 | c.2196G>C p.A732= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV62707435; called by muse, mutect2, varscan2
- PRAMEF2 | c.1395T>A p.S465= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV53572606; called by muse, mutect2, varscan2
- SFXN5 | c.987G>T p.T329= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV55584831; called by muse, mutect2, varscan2
- SLC8A3 | c.180G>T p.L60= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV63519133; called by muse, mutect2, varscan2
- SSTR1 | c.561C>T p.L187= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs765028121, COSV57454986, COSV99942843; called by muse, mutect2, varscan2
- TTC37 | c.1431G>A p.K477= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV62453527; called by muse, mutect2, varscan2
- UTP20 | c.3990T>C p.S1330= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV55372658; called by muse, mutect2, varscan2
- ZDHHC1 | c.1218G>T p.R406= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV52083442; called by muse, mutect2
- ZFHX4 | c.9156G>C p.P3052= | Silent (SNP) | VAF 15/181 reads (8%) | catalogued as COSV50509383, COSV50713544, COSV51491795; called by muse, mutect2
- H3-3B | chr17:75784733 C>T | 5'Flank (SNP) | VAF 13/42 reads (31%) | catalogued as rs377217779, COSV53139089; called by muse, mutect2, varscan2
- KIR3DX1 | n.36G>T | RNA (SNP) | VAF 39/176 reads (22%) | catalogued as COSV55596872; called by muse, mutect2, varscan2
